Surgical pathology report (de-identified scan), TCGA case TCGA-TS-A7OU, project TCGA-MESO (Mesothelioma), tissue source site University of Pennsylvania, specimen TCGA-TS-A7OU-01B (Primary Tumor).

[page 1 of 5]
Name

Physician:

Consult :
Copies

Print Date
Accession #
Date of Birth:

Sex : MALE
Age :

SURGICAL PATHOLOGY REPORT

DATE OF SURGERY :

DATE RECEIVED IN LAB :

CLINICAL INFORMATION:

-year-old male with large pleural effusion. Left video assisted thoracic surgery; biopsy showed mesothelioma.

Past medical history of elevated cholesterol, transient ischemic attack; no infectious precautions, has had previous biopsy.

Pre-Operative Diagnosis: Mesothelioma malignant epithelial type

Post-Operative Diagnosis: Mesothelioma malignant epithelial type

Operation: Laparoscopy; left thoracotomy; pneumonectomy

Specimen:

1. Laparoscopic peritoneal biopsies
2. Level 6 lymph node
3. Left lung
4. Diaphragm

ICD-O-3
Mesothelioma, epithelial NOS
9052/3
Site @ Pleura NOS
038.4
9/24/13

FROZEN SECTION DIAGNOSIS:

1FA: Fibrous tissue and skeletal muscle with chronic inflammation, no tumor seen.

Diagnosis given to Dr. at by

The case is received in four containers labeled with the patient's name and medical record number.

Specimen #1 was received fresh for frozen section diagnosis designated "Laparoscopic peritoneal biopsies". At that time, it was described as two pieces of red-tan, soft tissue measuring 0.3 x 0.2 x 0.1 cm and 1.0 x 0.1 x 0.1 cm, respectively. Both pieces of tissue are frozen in toto as 1FA. The specimen which was frozen is now received following formalin fixation and is submitted in toto as 1FA.

Specimen #2 is received in a formalin-filled container designated "Level 6 lymph node". The specimen consists of three pieces of anthracotic fibrofatty tissue measuring 0.7 x 0.6 x 0.2 cm, 0.6 x 0.4 x 0.1 cm and 0.5 x 0.3 x 0.1 cm, respectively. The specimen is submitted in toto as 2A.

Specimen #3 is received in a formalin-filled container designated "Left lung". The specimen consists of a left lung extrapleural pneumonectomy. There

Name:

Page: 1
Continue...

[page 2 of 5]
Print Date

Accession # [REDACTED]

Date of Birth: [REDACTED]

Name [REDACTED]

Sex : MALE

Age :

Physician: [REDACTED]

Consult :

Copies

SURGICAL PATHOLOGY REPORT

DATE OF SURGERY :

DATE RECEIVED IN LAB :

is a left upper and lower lobe of lung with endothoracic fascia covering the superior, lateral, medial, anterior and posterior surfaces of lung; there is a portion of diaphragm attached to the inferior lung surface. The specimen measures overall 27.5 cm superior to inferior, 16.2 cm anterior to posterior, and 4.6 cm medial to lateral. The portion of diaphragm measures 6.5 x 3.2 x 1.7 cm. A portion of pericardium is identified which is adherent to the medial surface of lung; the pericardium measures 16.0 x 9.8 x 0.2 cm. There is a portion of attached pericardial fat which measures 12.1 x 5.2 x 1.5 cm. The endothoracic fascia is notable for multiple nodularities covering the upper and lower lobes, there is a dominant nodule in the superior portion of the left upper lobe which measures 6.4 x 5.1 cm in area by at least 1.9 cm in thickness. The dominant nodule has a central ulceration which measures 1.7 cm. The other nodularities protrude through the endothoracic fascia and diffusely involve approximately 75% of the upper lobe, and 20% of the lower lobe. The nodules other than the dominant nodule range in size from 0.2 cm to 0.6 cm in maximum dimension. The pericardial surface of the specimen is smooth and is not grossly involved by a tumor. The portion of diaphragm is densely adherent to the lower lobe of lung. The diaphragm's margins of resection are firm, but no gross tumor is seen. In addition to the previously described nodularities there is a potential lymph node involved with tumor which is at the hilum, 1.2 cm from the trunk of the mainstem bronchus; this potential lymph node measures 3.1 x 1.5 x 1.3 cm and it is densely adherent to the hilar surface of the lung. In the hilum, there are multiple peribronchial and hilar lymph nodes; vascular margins of the upper and lower lobes are identified. Serially sectioning through the pneumonectomy specimen reveals that the previously described dominant nodule is a well circumscribed nodule with a heterogeneous, pink-white cut surface and a 0.2 cm thick capsule at the interface with the lung parenchyma. This nodule measures best in overall dimensions 6.0 x 4.5 cm, with a depth of extension into the parenchyma of 2.2 cm. Spreading from this lesion along the pleural surface, is a thickened plaque like material which ranges in depth between 0.1 cm and 0.6 cm; it diffusely involves the visceral pleura and endothoracic fascia. The lateral and posterior aspect of the upper lung is remarkable for a thickened gelatinous rind which ranges in size from 0.6 cm to 1.5 cm. This gelatinous rind has portions which are firm, and is contiguous with the previously described mass as well as areas of pleural thickening. An additional finding is a bleb-like space on the anterior portion of the left upper lung which measures 4.2 x 2.8 x 2.7 cm. It has a smooth grossly unremarkable lining, and appears walled off from the large airways of the specimen. The interlobar fissure appears to be fused but no gross tumor is seen within the fissure. The lower lobe has a thickened gelatinous rind similar to the one previously

Name: [REDACTED]

Page: 2

Continue...

[page 3 of 5]
Print Date
Accession
Date of Birth:

Name

Sex : MALE
Age :

Physician:

Consult :
Copies

SURGICAL PATHOLOGY REPORT

DATE OF SURGERY :

DATE RECEIVED IN LAB :

described in the upper lobe; it extends along the posterior aspect. Within the rind, there are several solid nodules ranging in size from 0.1 cm to 0.8 cm in maximum dimensions. The lateral, medial and anterior aspects of the lower lobe are grossly unremarkable. The inferior surface of the lower lobe is attached to the diaphragm over an area of 3.1 x 2.1 cm. Serial sectioning through the junction of the lung and the diaphragm reveals a diffuse plaque-like lesion within the interface. This lesion measures 3.2 x 1.4 x 5.1 cm. Examination of the pericardial surface reveals a vague diffuse nodularity with nodules ranging from 0.2 cm to 0.4 cm in size. Serial sectioning reveals that these nodularities do not communicate with the lung parenchyma. Further examination of the previously mentioned attached portion of pericardial fat reveals a hard, white nodularity measuring in size 1.1 x 0.8 x 0.3 cm. The remainder of the pericardial fat is grossly unremarkable. Representative sections are submitted as follows: 3A: Bronchial margin; 3B: Left upper lobe vascular margin; 3C: Left lower lobe vascular margin; 3D: Peribronchial lymph nodes; 3E: Hilar lymph nodes; 3F and 3G: 3.1 cm potential lymph node, hilar; 3H and 3I: Left upper lobe apex margin; 3J through 3L: Left upper lobe lateral margin; 3M through 3O: Left upper lobe posterior margin; 3P: Left upper lobe medial margin; 3Q: Left upper lobe anterior margin; 3R: Left upper lobe bleb; 3S: Interlobar fissure; 3T and 3U: Left lower lobe posterior-superior margin; 3V: Left lower lobe posterior margin; 3W: Left lower lobe lateral margin; 3X: Left lower lobe anterior margin; 3Y: Left lower lobe medial margin; 3Z: Left lower lobe in relation to diaphragm; 3AA: Left lower lobe inferior edge; 3AB: Anterior edge of diaphragm; 3AC: Posterior edge of diaphragm; 3AD: Medial edge of diaphragm; 3AE: Lateral edge of diaphragm; 3AF: Pericardium; 3AG: Nodule in pericardial fat; 3AH: Grossly unremarkable left upper lobe; 3AI: Grossly unremarkable left lower lobe.

Specimen #4 is received in a formalin-filled container designated "Diaphragm". The specimen consists of a portion of diaphragm measuring 8.2 x 6.5 x 1.2 cm. There is one surface which is smooth and glistening and is inked black; the opposite surface is red-tan and rough. The specimen is firm with no grossly identifiable nodules. The specimen is unoriented. The specimen is serially sectioned to reveal multiple white, plaque-like lesions adjacent to the surface opposite of the black ink; no nodularities are detected at the black inked surface. The remainder of the cut surface is grossly unremarkable muscle and fibrofatty tissue. Multiple full thickness representative sections are submitted as 4A through 4C.

SUMMARY OF SECTIONS: 40, multiple, representative
Dictator:

Name:

Page: 3
Continue...

[page 4 of 5]
Print Date
Accession #
Date of Birth: [REDACTED]

Name [REDACTED]

Sex : MALE
Age :

Physician: [REDACTED]

Consult :
Copies

SURGICAL PATHOLOGY REPORT

DATE OF SURGERY :
DATE RECEIVED IN LAB :

DATE OF SURGERY :
DATE RECEIVED IN LAB :

FINAL DIAGNOSIS:

1. Peritoneum, laparoscopic biopsies:
Fibrous tissue and skeletal muscle with chronic inflammation, no tumor seen.
2. Lymph node level 6, biopsy:
Three lymph nodes, no tumor seen (0/3).
3. Lung, left, total pneumonectomy:
- A. Diffuse malignant mesothelioma, epithelioid subtype, see note.
- B. Bronchial margin uninvolved.
- C. Tumor present within perivascular soft tissue at vascular margin.
- D. Tumor focally present at apical, lateral, posterior, medial and anterior margins, see note.
- E. Tumor involving pericardial fat and pericardium with focal positive margin.
- F. Tumor involving diaphragmatic pleura, no invasion of skeletal muscle seen, diaphragmatic margin free of tumor.
- G. Three peribronchial lymph nodes, no tumor seen (0/3).
- H. Three subpleural lymph nodes, no tumor seen (0/3).
- I. Thirteen hilar lymph nodes, no tumor seen (0/13).
- J. Changes consistent with previous talc pleurodesis
- K. Non-lesional lung, no specific pathologic change.
4. Diaphragm, partial resection:
- A. Malignant mesothelioma involving diaphragmatic pleura, no invasion of skeletal muscle seen, cauterized and deep inked margin free of tumor.
- B. Changes consistent with previous talc pleurodesis.

TY4400, T1X100, T13000, M43000, M09450
T08000, T08000, M09450
T28500, M90503, M03010, T29400, M80001, T31000, T31040, T13001, T26000, M09450,
T08000, M90503, M46360, T2Y700, M49000, M44000, T28000, M00100
TY2400, M90503, T13001

NOTE: The patient's prior biopsy from [REDACTED] has been reviewed.
This previous biopsy had a complete immunohistochemical work-up to confirm the

Name: [REDACTED]

Page: 4
Continue...

[page 5 of 5]
Print Date
Accession #
Date of Birth:

Name

Physician:

Sex : MALE
Age :

Consult :
Copies

DATE OF SURGERY :
DATE RECEIVED IN LAB :

diagnosis of malignant mesothelioma. In this resection specimen, there is a larger 6 cm tumor mass in the superior lateral aspect but the tumor can be seen to spread diffusely in the pleura in a manner typical of mesothelioma. There is extension along the interlobar fissure but there is no involvement of the underlying lung parenchyma.

PATHOLOGIST:

The case material was reviewed and the report
verified by:

(Electronic signature,

Name

Page: 5
End of Report

Source: NCI Genomic Data Commons file ebf87c58-fc95-4435-9061-c0ddfec5c79e (TCGA-TS-A7OU.662BCE15-BB09-43E6-813C-8713199581C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).